Somatic mutation profile of tumor specimen MMRF_1607_1_BM_CD138pos (aliquot MMRF_1607_1_BM_CD138pos_T2_KBS5U_K11921) from MMRF case MMRF_1607, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.5 years (20,990 days).
Specimen MMRF_1607_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ce935a5-3d2f-4ab0-9785-b4a28313e8eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1607_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1607_1_PB_Whole_C7_KBS5U_K11898; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68831f1e-7c6d-423e-8e19-cce4922237e9

The open-access MAF lists 80 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 20, Intron 10, Silent 9, RNA 4, 5'Flank 3, 5'UTR 3, Frame Shift Del 2, In Frame Del 2, Nonstop Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDKN1B | c.596A>T p.*199Lext*60 | Nonstop Mutation (SNP) | VAF 15/156 reads (10%) | catalogued as COSV57430013, COSV57431103; called by muse, mutect2
- CFAP46 | c.6833C>T p.P2278L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs148109095; called by muse, mutect2, varscan2
- COL27A1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 156/405 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs151285311, COSV61930189; called by muse, mutect2, varscan2
- HCN3 | c.284A>C p.Y95S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64233879; called by muse, varscan2
- HEATR6 | c.1696C>G p.Q566E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs747925167; called by muse, mutect2, varscan2
- IGHD2-2 | c.13T>G p.*5Eext*? | Nonstop Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as rs781843410; called by muse, mutect2
- IGLV3-1 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs61731694; called by muse, varscan2
- KLHL38 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs780844284; called by muse, mutect2, varscan2
- KLHL6 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs753462867, COSV58068939; called by muse, mutect2, varscan2
- LTB | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as rs1349235160; called by muse, varscan2
- RALBP1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1445245154; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1272+2T>G p.X424_splice | Splice Site (SNP) | VAF 43/144 reads (30%) | catalogued as COSV99624252; called by muse, mutect2, varscan2
- S1PR1 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV59513241; called by muse, mutect2, varscan2
- ST18 | c.2300A>G p.K767R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs764165724; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2020G>A p.V674I | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1423907331; called by muse, mutect2, varscan2
- ZNF728 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV74099654; called by muse, mutect2
- AC004997.1 | c.988T>G p.F330V | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ADCY6 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ADNP2 | c.2398C>A p.P800T | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARRDC2 | c.795del p.V266Wfs*36 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- GPN1 | c.940T>G p.S314A | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ILF3 | c.2634_2678del p.Q878_Y893delinsH | In Frame Del (DEL) | VAF 58/268 reads (22%) | called by mutect2, pindel
- IQCA1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTMR4 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOD2 | c.1785T>G p.S595R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- PARP10 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- PCNP | c.100_105del p.K34_T35del | In Frame Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- PLOD1 | c.153del p.F51Lfs*10 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- SEC22A | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SETD3 | c.103+2T>C p.X35_splice | Splice Site (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- ABCA12 | c.3783T>G p.S1261= (on ENST00000272895 / NM_173076.3; = p.S943= on NM_015657.3) | Silent (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- ABCA9 | c.637T>C p.L213= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1450815396; called by muse, mutect2
- DUOX1 | c.1500C>T p.I500= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as rs767254275, COSV58480100; called by muse, mutect2
- GABRR2 | c.408T>G p.P136= | Silent (SNP) | VAF 57/189 reads (30%) | catalogued as rs1468102664; called by muse, mutect2, varscan2
- HK2 | c.504G>A p.L168= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs367953381; called by muse, varscan2
- PCDH15 | c.4701C>T p.I1567= | Silent (SNP) | VAF 103/409 reads (25%) | catalogued as rs935682630, COSV64670324; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDE2 | c.573G>T p.R191= | Silent (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- SYNE1 | c.16968T>A p.T5656= (on ENST00000367255 / NM_182961.4; = p.T5585= on NM_033071.3) | Silent (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- ABCC9 | c.406+2230C>T | Intron (SNP) | VAF 16/63 reads (25%) | catalogued as rs1383094081; called by muse, mutect2, varscan2
- AC104057.1 | n.36G>A | RNA (SNP) | VAF 17/89 reads (19%) | catalogued as rs1378015545; called by muse, mutect2, varscan2
- ADGRG5 | c.-27G>A | 5'UTR (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- ADGRV1 | c.12120+131A>T | Intron (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- BDH1 | c.*1178C>T | 3'UTR (SNP) | VAF 10/18 reads (56%) | catalogued as rs533653262; called by muse, varscan2
- CLCN1 | c.*66G>A | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- CLEC2L | c.*120C>A | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- CREB5 | chr7:28409745 G>A | 5'Flank (SNP) | VAF 4/16 reads (25%) | catalogued as rs1297960347; called by muse, mutect2, varscan2
- CYGB | c.*109C>T | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- DPP6 | c.-4C>A | 5'UTR (SNP) | VAF 29/279 reads (10%) | called by muse, mutect2, varscan2
- DSCR4 | n.79C>T | RNA (SNP) | VAF 44/225 reads (20%) | catalogued as rs372701024; called by muse, mutect2, varscan2
- ELF2P4 | n.629C>T | RNA (SNP) | VAF 19/71 reads (27%) | catalogued as rs1419235527; called by muse, mutect2, varscan2
- ERCC6L2 | chr9:95875666 T>C | 5'Flank (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2
- F8 | c.*1120T>A | 3'UTR (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- FAM161A | c.*841A>G | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- IYD | c.688-1720G>A | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- KIF18A | c.*202G>A | 3'UTR (SNP) | VAF 6/124 reads (5%) | catalogued as rs1032678709; called by muse, mutect2
- LILRB2 | c.1361-44A>T | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- LMAN1 | c.*695T>G | 3'UTR (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- LTB | c.162+47G>A | Intron (SNP) | VAF 24/95 reads (25%) | catalogued as rs764564215; called by muse, mutect2, varscan2
- MAN2B2 | c.2933-520_2933-509del | Intron (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- MORC3 | c.*719dup | 3'UTR (INS) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- MYO1E | c.-2C>G | 5'UTR (SNP) | VAF 9/32 reads (28%) | catalogued as rs573448797, COSV55686570; called by muse, mutect2, varscan2
- NCOA3 | c.*1074T>G | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- PARP4P2 | n.800C>A | RNA (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- PCDH17 | c.*1834C>T | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- POLQ | chr3:121546502 C>T | 5'Flank (SNP) | VAF 22/122 reads (18%) | catalogued as rs774807420; called by muse, mutect2, varscan2
- PPME1 | c.1010-109G>C | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- PRRC1 | c.1129-796G>A | Intron (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- RELA | c.335+45G>T | Intron (SNP) | VAF 21/63 reads (33%) | called by mutect2, varscan2
- RPS25 | c.100-120G>C | Intron (SNP) | VAF 14/66 reads (21%) | catalogued as rs990515099; called by muse, mutect2
- RTP1 | c.*753G>A | 3'UTR (SNP) | VAF 63/138 reads (46%) | called by muse, mutect2, varscan2
- SEMA3A | c.*2696del | 3'UTR (DEL) | VAF 15/32 reads (47%) | called by mutect2, varscan2
- SLC4A1 | c.*1317G>C | 3'UTR (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2, varscan2
- SLC6A1 | c.*2220C>T | 3'UTR (SNP) | VAF 13/63 reads (21%) | catalogued as rs184515475, COSV55114006; called by muse, mutect2, varscan2
- SNTB2 | c.*6763_*6767del | 3'UTR (DEL) | VAF 5/21 reads (24%) | called by mutect2, varscan2
- SPZ1 | c.*249del | 3'UTR (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- SSR3 | c.*141T>C | 3'UTR (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
- TEX261 | c.*697C>G | 3'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- TRMT9B | c.*1457G>A | 3'UTR (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
